Somatic mutation profile of tumor specimen TCGA-D3-A1QA-06A (aliquot TCGA-D3-A1QA-06A-11D-A196-08) from TCGA case TCGA-D3-A1QA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.1 years (21,594 days).
Specimen TCGA-D3-A1QA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 739467d3-9f06-4ec1-ad70-fadad01a77b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1QA-10A (Blood Derived Normal), aliquot TCGA-D3-A1QA-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fb761ed-5d69-49d3-9524-60799e06d9f2

The open-access MAF lists 532 somatic variants for this specimen: 329 protein-altering or splice-affecting, 194 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 194, Nonsense Mutation 22, RNA 7, Splice Region 6, Splice Site 5, Intron 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL6IP1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs750623911, COSV58614680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 24/39 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 36/75 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- AADAC | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as rs867256779, COSV51759814; called by muse, mutect2, varscan2
- ABCA12 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55967719; called by muse, mutect2, varscan2
- ABCC11 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV100751153, COSV62324618; called by muse, mutect2, varscan2
- ABCC9 | c.1802+1G>A p.X601_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV53979045; called by muse, mutect2, varscan2
- AC090517.4 | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs775517683, COSV99974445; called by muse, mutect2, varscan2
- ACE | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs780299861, COSV52003247; called by muse, mutect2, varscan2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADCY1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV52038699; called by muse, mutect2, varscan2
- ADD1 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296425; called by mutect2, varscan2
- ADD2 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781966159, COSV52462784; called by muse, mutect2, varscan2
- ADGRG4 | c.4475C>T p.P1492L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54952084, COSV54962014; called by muse, mutect2, varscan2
- ADGRV1 | c.1913A>G p.N638S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs201262529, COSV67990520; called by muse, mutect2, varscan2
- ADGRV1 | c.15730C>T p.L5244F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.216); catalogued as COSV67990522; called by muse, mutect2, varscan2
- AFF1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV57122047; called by mutect2, varscan2
- AFF3 | c.2793G>A p.T931= | Splice Region (SNP) | VAF 32/76 reads (42%) | catalogued as COSV57840510; called by muse, mutect2, varscan2
- AGA | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764539498, COSV52807062; called by muse, mutect2, varscan2
- AGBL1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs201541206; called by muse, mutect2, varscan2
- AKNAD1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs369675579; called by muse, mutect2, varscan2
- AL645922.1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 267/389 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV64888213; called by muse, mutect2, varscan2
- AMY1C | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs763143846, COSV100915192; called by muse, varscan2
- ANAPC16 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as rs1219678101, COSV54965251; called by muse, varscan2
- ANKS1B | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1252788622, COSV59116505; called by muse, mutect2, varscan2
- ANKS1B | c.1838C>T p.S613F | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752498375, COSV61362691; called by muse, mutect2, varscan2
- ANO1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs778999525, COSV60284006; called by muse, mutect2, varscan2
- ARHGAP32 | c.5841G>C p.E1947D (on ENST00000310343 / NM_001378025.1; = p.E1598D on NM_014715.4) | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV59852101; called by muse, mutect2, varscan2
- ARHGEF12 | c.3941C>T p.P1314L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63105587; called by muse, mutect2, varscan2
- ARSH | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV66963505; called by muse, mutect2, varscan2
- ATG10 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56429080; called by muse, mutect2, varscan2
- ATP10D | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV56710299; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 51/128 reads (40%) | catalogued as COSV57750726; called by muse, varscan2
- BAZ2B | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54276307; called by muse, mutect2, varscan2
- BDP1 | c.5456C>T p.S1819F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV62432796; called by muse, mutect2, varscan2
- BSN | c.11702C>T p.P3901L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as rs1221419130, COSV56523062; called by muse, mutect2, varscan2
- CA3 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV53410527; called by muse, mutect2, varscan2
- CACNA1E | c.5690C>T p.P1897L | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV62406719; called by muse, mutect2, varscan2
- CACNA1S | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV62939767; called by muse, mutect2, varscan2
- CALR3 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54169091, COSV54171013; called by muse, mutect2, varscan2
- CANT1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 104/177 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56606113; called by muse, mutect2, varscan2
- CAPSL | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as COSV68438824; called by muse, mutect2, varscan2
- CAPZA3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV56856262; called by muse, mutect2, varscan2
- CASS4 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV64387442; called by muse, mutect2, varscan2
- CAVIN2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748628852, COSV58424893; called by muse, mutect2, varscan2
- CBX8 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as COSV53937080; called by muse, mutect2, varscan2
- CCDC63 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57526812; called by muse, mutect2, varscan2
- CCDC88C | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774584774, COSV66239736; called by muse, mutect2, varscan2
- CCER1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV62647792; called by muse, mutect2, varscan2
- CCNT1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1397516301, COSV56064325; called by muse, mutect2, varscan2
- CD200R1 | c.603G>T p.K201N (on ENST00000471858 / NM_170780.3; = p.K224N on NM_138806.4) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV55602257; called by muse, mutect2, varscan2
- CD40 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV64847472; called by muse, varscan2
- CDH7 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59882882; called by muse, mutect2, varscan2
- CDH8 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV54876173; called by muse, mutect2, varscan2
- CFH | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62777161; called by muse, mutect2, varscan2
- CFHR4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52228832; called by muse, varscan2
- CFHR5 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56824789; called by muse, mutect2, varscan2
- CHD4 | c.1381C>T p.H461Y (on ENST00000357008 / NM_001363606.2; = p.H474Y on NM_001273.5) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as rs187920601, COSV58906144; called by muse, mutect2, varscan2
- CHD7 | c.7502C>T p.S2501F | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV71112847; called by muse, mutect2, varscan2
- CIITA | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV60855176, COSV60859872; called by muse, mutect2, varscan2
- CLASP1 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55331327; called by muse, mutect2, varscan2
- CLCN1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 110/132 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1198219818, COSV58370677, COSV58372294, COSV58375171; called by muse, mutect2, varscan2
- CLIP1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs539818652, COSV56805277; called by muse, mutect2, varscan2
- CLP1 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 84/181 reads (46%) | catalogued as rs754578147, COSV57055165; called by muse, mutect2, varscan2
- CNOT3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360288; called by muse, mutect2, varscan2
- COL28A1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68082625; called by muse, mutect2, varscan2
- COL4A3 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67418987, COSV67421880; called by muse, mutect2, varscan2
- COL5A1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.63); PolyPhen benign (0.245); catalogued as COSV65672129; called by muse, mutect2, varscan2
- COL5A3 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53415231; called by muse, mutect2, varscan2
- COL7A1 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs748398314, COSV60398757; called by muse, mutect2, varscan2
- COL7A1 | c.1341A>T p.E447D | Missense Mutation (SNP) | VAF 67/114 reads (59%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV60398766; called by muse, mutect2, varscan2
- COPG2 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV56229204; called by muse, mutect2
- CPXM2 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53866694; called by muse, mutect2, varscan2
- CRISP3 | c.139C>T p.P47S (on ENST00000371159 / NM_001368123.1; = p.P29S on NM_006061.4) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as COSV53821303; called by muse, mutect2, varscan2
- CRYBG1 | c.5581G>A p.G1861S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV64813395; called by muse, mutect2, varscan2
- CTNNA3 | c.2265G>A p.Q755= | Splice Region (SNP) | VAF 39/86 reads (45%) | catalogued as rs1485947386, COSV65526854; called by muse, mutect2, varscan2
- CUBN | c.6949C>T p.R2317* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs368153709; called by muse, mutect2, varscan2
- CYP11A1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as COSV51433712; called by muse, mutect2, varscan2
- CYP2B6 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs565980641, COSV57844897; called by muse, mutect2, varscan2
- CYTIP | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51634797; called by muse, mutect2, varscan2
- D2HGDH | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58322348; called by muse, mutect2, varscan2
- DAB1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs1249528208, COSV59732419, COSV59734897; called by muse, varscan2
- DDB2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV57039788; called by muse, mutect2, varscan2
- DICER1 | c.1752G>A p.K584= | Splice Region (SNP) | VAF 53/124 reads (43%) | catalogued as COSV58624320; called by muse, mutect2, varscan2
- DISP2 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.09); catalogued as COSV51130237; called by muse, mutect2, varscan2
- DISP3 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs752388200, COSV53832931, COSV99608662; called by muse, varscan2
- DLEC1 | c.3952G>A p.D1318N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100342190; called by muse, varscan2
- DMRT1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66519711, COSV66522899; called by muse, varscan2
- DNAH11 | c.11654G>T p.R3885I | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs772385542, COSV60967206; called by muse, mutect2, varscan2
- DNAH2 | c.7670C>T p.P2557L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66722740; called by muse, mutect2, varscan2
- DNAH5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV54239692; called by muse, mutect2, varscan2
- DNAH8 | c.5855G>A p.G1952E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547570, COSV59464962; called by muse, mutect2
- DNAJC14 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 50/115 reads (43%) | catalogued as COSV57913699; called by mutect2, varscan2
- DNPEP | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1182494773, COSV56110187; called by muse, mutect2, varscan2
- DOCK3 | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs868494898, COSV56532166; called by muse, mutect2, varscan2
- DOCK7 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.697); catalogued as rs772279022, COSV52014059; called by muse, mutect2, varscan2
- DOK7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV60773095; called by muse, mutect2, varscan2
- DSCAM | c.5840C>T p.P1947L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV68031640; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DUSP22 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739740; called by muse, mutect2, varscan2
- EDC3 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59341057; called by muse, mutect2, varscan2
- EFCAB6 | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs915086992, COSV53061397; called by muse, mutect2, varscan2
- ELMO2 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs761017231, COSV51684580; called by muse, mutect2, varscan2
- ELOA2 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55303510; called by muse, mutect2, varscan2
- EPB41 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100548440; called by muse, mutect2, varscan2
- EPB41L4B | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV65797886; called by muse, mutect2, varscan2
- EPG5 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs368719987, COSV56352878; called by muse, mutect2, varscan2
- EPHA7 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV65187742; called by muse, mutect2, varscan2
- EPHB4 | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV62269733; called by muse, mutect2, varscan2
- EPHB6 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63892679; called by muse, mutect2, varscan2
- EPN3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 69/106 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs960657866, COSV52141502; called by muse, mutect2, varscan2
- ERAP1 | c.2819-1G>A p.X940_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99700911; called by muse, mutect2, varscan2
- ERICH3 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.209); catalogued as rs866558257, COSV58599808; called by muse, mutect2, varscan2
- ERICH3 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58612733; called by muse, mutect2, varscan2
- ERICH6 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55801921; called by muse, mutect2, varscan2
- F2RL3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451124365, COSV50186038; called by mutect2, varscan2
- F8 | c.6845C>T p.S2282F | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1314187, COSV57705909; called by muse, mutect2, varscan2
- FAM83B | c.411A>T p.E137D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60924479; called by mutect2, varscan2
- FAM83B | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs868381299, COSV60922538; called by muse, mutect2, varscan2
- FAP | c.1815-1G>A p.X605_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV51864075, COSV51864774; called by muse, mutect2, varscan2
- FAR1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61385592; called by muse, mutect2, varscan2
- FBXO22 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358440360, COSV57618186; called by muse, mutect2, varscan2
- FBXO24 | c.859G>A p.V287I (on ENST00000241071 / NM_033506.3; = p.V325I on NM_012172.5) | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV53827931; called by muse, mutect2, varscan2
- FBXO42 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV65046357; called by muse, mutect2, varscan2
- FCMR | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65568225; called by muse, mutect2, varscan2
- FGD5 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767834243, COSV53247490; called by muse, mutect2, varscan2
- FLNB | c.6291G>C p.E2097D | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55869104, COSV55886928; called by muse, mutect2, varscan2
- FRMD7 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53747683; called by muse, mutect2, varscan2
- FRY | c.1973G>A p.W658* | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as COSV66574444; called by muse, mutect2, varscan2
- GCC1 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 135/170 reads (79%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV58463220; called by muse, mutect2, varscan2
- GIMAP4 | c.161A>T p.K54I | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55433728; called by mutect2, varscan2
- GIMAP7 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57959455; called by muse, mutect2, varscan2
- GPR37 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs1305258653, COSV58255272; called by muse, mutect2, varscan2
- GPR37L1 | c.964A>C p.I322L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV66162602; called by muse, varscan2
- GRIA1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as COSV99599656; called by muse, mutect2, varscan2
- GRIN2A | c.4048G>A p.D1350N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.224); catalogued as COSV58037875; called by muse, mutect2, varscan2
- GUCA1B | c.525G>A p.W175* | Nonsense Mutation (SNP) | VAF 53/135 reads (39%) | catalogued as COSV50004769; called by muse, mutect2, varscan2
- GYS2 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs755758873, COSV53926100; called by muse, varscan2
- H2BC4 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58414879, COSV58417027; called by muse, varscan2
- HAS1 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1280765977, COSV55788560; called by muse, mutect2, varscan2
- HCN1 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV57524694; called by mutect2, varscan2
- HECTD4 | c.8468C>T p.P2823L | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66395885; called by muse, mutect2, varscan2
- HFM1 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54032721; called by mutect2, varscan2
- HHIPL2 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58566348; called by muse, mutect2, varscan2
- HIF3A | c.1441-1G>A p.X481_splice (on ENST00000377670 / NM_152795.4; = p.X412_splice on NM_022462.4) | Splice Site (SNP) | VAF 37/88 reads (42%) | catalogued as COSV52201864; called by muse, mutect2, varscan2
- HINT2 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 100/168 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.414); catalogued as COSV99427865; called by muse, mutect2, varscan2
- HJV | c.1217C>T p.S406F (on ENST00000336751 / NM_213653.4; = p.S293F on NM_145277.5) | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60952693; called by muse, mutect2, varscan2
- HMGCS1 | c.1173T>G p.D391E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57290897; called by muse, mutect2, varscan2
- HOXD10 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV50893177; called by muse, mutect2, varscan2
- HPS4 | c.502-1G>A p.X168_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61104402; called by muse, mutect2, varscan2
- HTN3 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV66879688; called by mutect2, varscan2
- HYDIN | c.13223G>A p.G4408E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101125069; called by muse, mutect2, varscan2
- IFT43 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99466039; called by muse, mutect2, varscan2
- IGKV3-11 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs780668733; called by muse, mutect2, varscan2
- IGKV6D-41 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs754944714; called by muse, mutect2, varscan2
- IL21 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV52646098, COSV52646508; called by muse, mutect2, varscan2
- INHBB | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV54678124, COSV54678680; called by muse, mutect2, varscan2
- ITGB6 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943658539, COSV51796570; called by muse, mutect2, varscan2
- ITPR3 | c.5149G>A p.D1717N | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); catalogued as COSV65412339; called by muse, mutect2, varscan2
- JAKMIP2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54609259; called by muse, mutect2, varscan2
- KALRN | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53755097, COSV99563522; called by muse, mutect2, varscan2
- KAT2B | c.522T>A p.C174* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV55432093; called by muse, mutect2, varscan2
- KCNA1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV66838110; called by mutect2, varscan2
- KCNB2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs756118503, COSV73049946; called by muse, mutect2, varscan2
- KCNG4 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1433852981, COSV57583799; called by mutect2, varscan2
- KCNH1 | c.2753C>T p.P918L (on ENST00000271751 / NM_172362.3; = p.P891L on NM_002238.4) | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV55092021; called by muse, mutect2, varscan2
- KCNH5 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as rs1406901112, COSV59768376; called by muse, mutect2, varscan2
- KCNK1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs185527931, COSV64035668; called by muse, mutect2, varscan2
- KDM2B | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs769097932, COSV65643088; called by muse, mutect2, varscan2
- KHNYN | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs760232261, COSV52159120; called by muse, mutect2, varscan2
- KIAA1210 | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV68178593; called by muse, mutect2, varscan2
- KIF19 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63430047; called by muse, mutect2, varscan2
- KIF20B | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755409283, COSV53311374; called by mutect2, varscan2
- KLK3 | c.495C>T p.F165= | Splice Region (SNP) | VAF 70/140 reads (50%) | catalogued as rs749770722, COSV58101657; called by muse, mutect2, varscan2
- KMT2A | c.5299C>T p.P1767S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV63289689; called by muse, mutect2, varscan2
- KMT2C | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV51470450; called by muse, mutect2, varscan2
- KRT14 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51422186; called by mutect2, varscan2
- KRT23 | c.316A>C p.K106Q | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52928489; called by muse, mutect2, varscan2
- KRT3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751579090, COSV58814476; called by mutect2, varscan2
- KRT6C | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs200158036, COSV52878944; called by muse, mutect2, varscan2
- KYAT3 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53103563; called by muse, mutect2, varscan2
- LAMA3 | c.6055G>A p.G2019R (on ENST00000313654 / NM_198129.4; = p.G410R on NM_000227.6) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52538826; called by muse, mutect2, varscan2
- LGI2 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 106/236 reads (45%) | catalogued as rs759918108, COSV66122387, COSV66122923; called by muse, varscan2
- LIFR | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs766013625, COSV54695092; called by muse, mutect2, varscan2
- LPA | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.318); catalogued as COSV60305900; called by muse, mutect2, varscan2
- LPAR3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV65454328; called by muse, mutect2, varscan2
- LRP1 | c.6613G>A p.E2205K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV54518651; called by muse, mutect2, varscan2
- LTBP1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1191865315, COSV63192960; called by muse, mutect2, varscan2
- MACF1 | c.20045C>T p.A6682V (on ENST00000372915; = p.A4727V on NM_012090.5) | Missense Mutation (SNP) | VAF 50/96 reads (52%) | catalogued as COSV99244100; called by muse, mutect2, varscan2
- MAGI1 | c.3161G>A p.G1054E (on ENST00000402939 / NM_001033057.2; = p.G1083E on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/254 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58315653; called by muse, mutect2, varscan2
- MAPK4 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs757002674, COSV68542156; called by muse, varscan2
- MAST3 | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53229084; called by mutect2, varscan2
- MED12L | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs533044099, COSV56387740; called by muse, mutect2, varscan2
- MEP1A | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs746944566, COSV57921438; called by muse, mutect2, varscan2
- MLH1 | c.1520T>A p.L507* | Nonsense Mutation (SNP) | VAF 92/255 reads (36%) | catalogued as CD117358, COSV51621303; called by muse, mutect2, varscan2
- MMP24 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771740; called by muse, mutect2, varscan2
- MMP3 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55407122; called by muse, mutect2, varscan2
- MOCS3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs757020762, COSV54867207; called by muse, mutect2, varscan2
- MOG | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 73/266 reads (27%) | catalogued as COSV65306585; called by muse, mutect2, varscan2
- MORC1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs748962195, COSV51725516, COSV99227366; called by muse, mutect2, varscan2
- MORC1 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51725524; called by muse, mutect2, varscan2
- MPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs767641039, COSV61731060; called by muse, varscan2
- MUC16 | c.21521C>T p.A7174V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.682); catalogued as rs1414361895, COSV67479755; called by muse, mutect2, varscan2
- MUC16 | c.11671G>A p.E3891K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV67479759; called by muse, mutect2, varscan2
- MUC16 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1206703719, COSV67479762; called by muse, mutect2, varscan2
- MUC17 | c.7882C>T p.P2628S | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV60296132; called by muse, mutect2, varscan2
- MUC5AC | c.13984G>A p.E4662K | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.17); catalogued as COSV64371091; called by muse, mutect2, varscan2
- MUC5B | c.6688C>T p.P2230S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as COSV71594202; called by mutect2, varscan2
- MUC5B | c.10840G>A p.G3614S | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV71594203; called by muse, mutect2, varscan2
- MUSK | c.2009T>G p.M670R | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV51890958; called by muse, mutect2, varscan2
- MVB12A | c.192C>T p.N64= | Splice Region (SNP) | VAF 16/34 reads (47%) | catalogued as COSV57679300; called by muse, mutect2, varscan2
- MVP | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754544174, COSV62422781; called by muse, mutect2, varscan2
- MYBPH | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55143392; called by muse, mutect2, varscan2
- MYH1 | c.4756G>A p.E1586K | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56852376, COSV99875531; called by muse, mutect2, varscan2
- MYH1 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV56852997; called by muse, mutect2, varscan2
- MYH15 | c.1791G>A p.V597= | Splice Region (SNP) | VAF 47/124 reads (38%) | catalogued as COSV56315110; called by muse, mutect2, varscan2
- MYLK | c.4525G>A p.E1509K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60615865; called by muse, mutect2, varscan2
- MYLK | c.4134G>A p.W1378* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV60615884; called by muse, mutect2, varscan2
- MYO18B | c.6478G>A p.E2160K | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs371851187; called by muse, mutect2, varscan2
- MYO3B | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV58710069; called by muse, mutect2, varscan2
- NBEA | c.4588C>T p.P1530S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV59803745; called by muse, mutect2, varscan2
- NCKAP1L | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV53209768; called by mutect2, varscan2
- NCOA6 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1044080467, COSV62865796; called by mutect2, varscan2
- NEFL | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55336588; called by muse, mutect2, varscan2
- NETO1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs745312225, COSV55010235; called by muse, varscan2
- NEURL1 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV63915087; called by muse, mutect2, varscan2
- NFE2L3 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs761143940, COSV50232665; called by muse, mutect2, varscan2
- NGLY1 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54988496; called by muse, mutect2, varscan2
- NKAIN1 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV55275134; called by muse, mutect2, varscan2
- NLN | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1402294853, COSV66766531; called by muse, mutect2, varscan2
- NOD2 | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1238071864, COSV100318893, COSV56053095; called by muse, mutect2, varscan2
- NOS1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs147820513, COSV57606244; called by muse, mutect2, varscan2
- NOTCH2 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56685389; called by muse, mutect2, varscan2
- NSD2 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56393653; called by muse, mutect2, varscan2
- NSD3 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV57620750, COSV57622070; called by muse, mutect2, varscan2
- NTSR1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs201305649, COSV65139115; called by muse, mutect2, varscan2
- NUAK1 | c.1664G>C p.G555A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV54605818, COSV54607908; called by muse, mutect2, varscan2
- OPRD1 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52382870; called by muse, mutect2
- OR1A2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV67936640; called by muse, mutect2, varscan2
- OR4E2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484781211, COSV57731410; called by muse, mutect2, varscan2
- OR51B6 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV66513502; called by muse, mutect2, varscan2
- OR8D2 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62488078, COSV62488750; called by muse, mutect2, varscan2
- OVCH1 | c.3137G>A p.G1046E | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV58965706, COSV58969965; called by muse, mutect2, varscan2
- P2RY13 | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56368114, COSV56387757; called by muse, mutect2, varscan2
- PAPPA2 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100866770; called by mutect2, varscan2
- PARP8 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.968); catalogued as rs1239600215, COSV55863353; called by muse, mutect2, varscan2
- PCDH17 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64976647; called by mutect2, varscan2
- PCDH8 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.241); catalogued as rs769364797, COSV58814145; called by muse, mutect2, varscan2
- PCDHGC4 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1285988124, COSV52759049; called by muse, mutect2, varscan2
- PDE9A | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs1393435353, COSV52328988; called by muse, mutect2, varscan2
- PGBD1 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 90/116 reads (78%) | catalogued as rs778004869, COSV52554801; called by muse, mutect2, varscan2
- PHF21B | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV57560188; called by muse, mutect2, varscan2
- PIK3C2G | c.3436A>T p.I1146F (on ENST00000676171; = p.I1105F on NM_004570.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV56820527; called by muse, mutect2, varscan2
- PITX2 | c.409C>T p.R137W (on ENST00000354925 / NM_001204397.1; = p.R144W on NM_000325.6) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60741653; called by muse, mutect2, varscan2
- PLA1A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs753363283, COSV56331872; called by muse, mutect2, varscan2
- PPA2 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774246908, COSV58997050; called by muse, mutect2, varscan2
- PPP1R3B | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV60099947; called by muse, varscan2
- PPP1R3B | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs200095175; called by muse, varscan2
- PPP2R3A | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as COSV53867652, COSV53869171; called by muse, mutect2, varscan2
- PPP2R5E | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV61743233; called by muse, mutect2, varscan2
- PPP4R4 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58556641; called by muse, mutect2
- PRAMEF14 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs199937476; called by muse, mutect2, varscan2
- PRAMEF4 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV52438627; called by muse, mutect2, varscan2
- PREX2 | c.3533G>A p.G1178E | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55775786, COSV55786310, COSV99905418; called by muse, mutect2, varscan2
- PRICKLE1 | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs780974681, COSV61544770; called by muse, mutect2, varscan2
- PRLR | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51493269; called by muse, mutect2, varscan2
- PRMT5 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53547385; called by muse, mutect2, varscan2
- PSG8 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV60609191; called by muse, mutect2, varscan2
- PSMG2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50867868; called by muse, mutect2, varscan2
- PTCHD3 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs868283717, COSV71257137; called by muse, mutect2, varscan2
- PTPRB | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs778294640, COSV54241229; called by muse, mutect2, varscan2
- PTPRD | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV61928174; called by muse, varscan2
- PTPRT | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs724159835, COSV61966941; called by muse, mutect2, varscan2
- R3HDM1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV51528670; called by muse, mutect2, varscan2
- RANBP17 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV66653734; called by muse, mutect2, varscan2
- RBL2 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 189/379 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1454341915, COSV50882691; called by muse, mutect2, varscan2
- RIOK2 | c.813T>A p.D271E | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV51613896; called by muse, mutect2, varscan2
- RPL26L1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54199990; called by mutect2, varscan2
- RXFP1 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV57053426; called by muse, mutect2, varscan2
- RYR3 | c.7349G>A p.R2450K (on ENST00000389232; = p.R2451K on NM_001036.6) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66800908; called by muse, mutect2, varscan2
- S100A7A | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs765575828, COSV61330896; called by muse, mutect2, varscan2
- SAA1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs533793779, COSV62946509; called by muse, mutect2, varscan2
- SAAL1 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV55516629; called by muse, mutect2, varscan2
- SAMD9 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as rs753744139, COSV66076732; called by muse, mutect2, varscan2
- SBNO1 | c.2732C>T p.S911F (on ENST00000420886; = p.S910F on NM_018183.5) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV57343767; called by muse, mutect2, varscan2
- SCN11A | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV56566193, COSV56581194; called by muse, mutect2, varscan2
- SCN7A | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101313206; called by muse, mutect2, varscan2
- SELE | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV60976789, COSV60978469; called by muse, mutect2, varscan2
- SELL | c.1150C>T p.P384S (on ENST00000650983; = p.P371S on NM_000655.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV52553595; called by muse, mutect2, varscan2
- SI | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100015427; called by muse, mutect2, varscan2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by mutect2, varscan2
- SLC13A1 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52014263; called by muse, mutect2, varscan2
- SLC22A3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.051); catalogued as rs201195713, COSV51717956; called by muse, mutect2, varscan2
- SLC36A3 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV58857608; called by muse, mutect2
- SLC9A4 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54834252; called by muse, mutect2, varscan2
- SLITRK3 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV53850809; called by muse, mutect2, varscan2
- SMOC1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV62762437; called by mutect2, varscan2
- SPAG5 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs778639150, COSV58803039; called by muse, mutect2, varscan2
- SPRY3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV57143676; called by muse, mutect2, varscan2
- SPTA1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148714399, COSV63754963; called by muse, mutect2, varscan2
- SPTA1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV63756757; called by muse, mutect2, varscan2
- SRPK1 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60414493, COSV60415555; called by muse, mutect2, varscan2
- ST18 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs867547514, COSV52490872; called by muse, mutect2, varscan2
- SZT2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100726298; called by muse, mutect2, varscan2
- TAAR8 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1562357077, COSV51586735; called by muse, varscan2
- TAB1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53372293; called by muse, mutect2, varscan2
- TACC2 | c.3350T>A p.F1117Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); catalogued as COSV57764104; called by mutect2, varscan2
- TBX18 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762981355, COSV63737501; called by mutect2, varscan2
- TEX45 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV64463769; called by muse, mutect2, varscan2
- THEMIS | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64069509, COSV64072689; called by muse, mutect2, varscan2
- TRIM24 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58975305; called by muse, mutect2
- TRIM60 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs535129175, COSV61969990, COSV61971708; called by muse, mutect2, varscan2
- TRPM2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV55973215; called by muse, mutect2, varscan2
- TRRAP | c.6152C>T p.S2051F (on ENST00000359863 / NM_001244580.1; = p.S2033F on NM_003496.3) | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV62849715; called by muse, mutect2, varscan2
- UNC93A | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV57809681; called by muse, mutect2, varscan2
- VRK2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs201406382, COSV60877884; called by muse, mutect2, varscan2
- WDR76 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.006); catalogued as COSV51040097; called by muse, mutect2, varscan2
- ZBTB45 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV54018611, COSV54020773; called by muse, mutect2, varscan2
- ZNF28 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV60424367; called by muse, mutect2, varscan2
- ZNF474 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs778268020, COSV56946852; called by mutect2, varscan2
- ATP2C1 | c.749_751del p.A250del | In Frame Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- ECPAS | c.4980dup p.L1661Tfs*2 | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MAGEB6B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PDXDC1 | c.842_843del p.Y281Cfs*12 | Frame Shift Del (DEL) | VAF 91/512 reads (18%) | called by mutect2, pindel, varscan2
- TYK2 | c.3315del p.T1106Rfs*7 | Frame Shift Del (DEL) | VAF 43/155 reads (28%) | called by pindel, varscan2
- ZMAT4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.198); called by muse, mutect2
- ABCA7 | c.2842C>T p.L948= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV54028354; called by muse, mutect2, varscan2
- ABCB1 | c.1095C>T p.I365= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV55954238, COSV55957018; called by muse, mutect2, varscan2
- ABCC9 | c.4206C>T p.S1402= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV53979029, COSV99686695; called by muse, varscan2
- ADAR | c.3415C>T p.L1139= | Silent (SNP) | VAF 61/131 reads (47%) | catalogued as COSV52718209; called by muse, mutect2, varscan2
- ADGRA1 | c.1251C>T p.G417= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1337834498, COSV63416714; called by muse, mutect2, varscan2
- ADH1B | c.789G>A p.V263= | Silent (SNP) | VAF 97/236 reads (41%) | catalogued as COSV59297617; called by muse, mutect2, varscan2
- AHCTF1 | c.2964C>T p.F988= (on ENST00000366508; = p.F962= on NM_015446.5) | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs772184798, COSV58252699; called by muse, mutect2, varscan2
- ANO3 | c.1956C>T p.S652= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV56799973; called by muse, mutect2, varscan2
- ASTN2 | c.3501C>T p.F1167= (on ENST00000313400 / NM_001365069.1; = p.F1116= on NM_014010.5) | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV56009942; called by muse, mutect2, varscan2
- ASTN2 | c.1101C>T p.I367= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as rs140458736; called by mutect2, varscan2
- ATP10A | c.4053C>T p.S1351= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs1033392672, COSV63520563; called by muse, mutect2, varscan2
- B4GALNT3 | c.2652C>T p.F884= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV56755451; called by muse, varscan2
- BPIFA2 | c.264C>T p.V88= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV53612011; called by muse, mutect2, varscan2
- BTD | c.906C>T p.Y302= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV57729850; called by muse, mutect2, varscan2
- BTN3A1 | c.1455C>T p.F485= | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as COSV50025088; called by muse, mutect2, varscan2
- C1orf127 | c.1896C>T p.L632= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV65438056; called by muse, mutect2, varscan2
- CACNA1C | c.4425C>T p.I1475= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as CM152261, COSV59745645; called by muse, mutect2, varscan2
- CACNA1E | c.3906C>T p.I1302= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV62384362; called by muse, mutect2, varscan2
- CACNA1E | c.4755G>A p.K1585= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV62392082, COSV62406708; called by muse, mutect2, varscan2
- CALB2 | c.294C>T p.F98= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV56940863; called by muse, mutect2, varscan2
- CAPN13 | c.975C>T p.I325= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs780049705, COSV54432961; called by muse, mutect2, varscan2
- CCDC141 | c.1767C>T p.I589= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV55377947; called by muse, mutect2, varscan2
- CDCP2 | c.345C>T p.T115= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV61284836; called by muse, mutect2, varscan2
- CDH7 | c.1179G>A p.G393= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs746477198, COSV59882891; called by muse, mutect2, varscan2
- CDKN3 | c.510C>T p.S170= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1173121820, COSV53593466; called by mutect2, varscan2
- CELSR1 | c.4341C>T p.F1447= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV53094821; called by muse, mutect2, varscan2
- CFTR | c.609C>T p.I203= | Silent (SNP) | VAF 66/119 reads (55%) | catalogued as rs1800081, CM043462, COSV50073612; called by muse, mutect2, varscan2
- CFTR | c.2721C>T p.I907= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1384524504, COSV50073706; called by muse, varscan2
- CLCN7 | c.1746C>T p.P582= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs768693668, COSV51972105; called by muse, mutect2, varscan2
- CLINT1 | c.489C>T p.S163= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV51626813; called by muse, mutect2, varscan2
- CLTCL1 | c.888C>T p.N296= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as COSV54234935; called by muse, mutect2, varscan2
- CMPK2 | c.1116C>T p.I372= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV56775512; called by muse, mutect2, varscan2
- CNGA1 | c.739C>T p.L247= | Silent (SNP) | VAF 56/138 reads (41%) | catalogued as COSV62055541; called by muse, mutect2, varscan2
- CNTNAP3 | c.3750G>A p.V1250= | Silent (SNP) | VAF 63/483 reads (13%) | catalogued as rs1165017151; called by muse, mutect2, varscan2
- COQ10A | c.361C>T p.L121= | Silent (SNP) | VAF 70/150 reads (47%) | catalogued as COSV57525434; called by muse, mutect2, varscan2
- CRB1 | c.2265G>A p.L755= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV66331897; called by muse, mutect2, varscan2
- CSMD2 | c.5670C>T p.I1890= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as COSV53904435; called by muse, varscan2
- CTSB | c.195G>A p.G65= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs779094537, COSV61540978; called by muse, mutect2, varscan2
- CTSG | c.759C>T p.T253= | Silent (SNP) | VAF 91/217 reads (42%) | catalogued as rs771803667, COSV53534719, COSV53536287; called by muse, mutect2, varscan2
- CYFIP2 | c.1551C>T p.I517= | Silent (SNP) | VAF 220/484 reads (45%) | catalogued as rs1475214519, COSV59045202; called by mutect2, varscan2
- CYP1A1 | c.1389C>A p.A463= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV101122296; called by mutect2, varscan2
- CYP2C9 | c.1381C>T p.L461= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV53250786; called by muse, mutect2, varscan2
- DDX52 | c.541C>T p.L181= | Silent (SNP) | VAF 97/151 reads (64%) | catalogued as rs759818696; called by muse, mutect2, varscan2
- DLEC1 | c.3951G>A p.R1317= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100342184; called by muse, varscan2
- DMGDH | c.1077G>A p.L359= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1367152995, COSV54866378; called by muse, mutect2, varscan2
- DNAH11 | c.12219G>A p.K4073= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV60967212; called by muse, mutect2, varscan2
- DNAH3 | c.7254G>A p.R2418= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV54536369; called by muse, mutect2, varscan2
- DNAJC6 | c.1701C>T p.T567= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV54778553; called by muse, mutect2, varscan2
- DOCK7 | c.3147C>T p.V1049= (on ENST00000635253 / NM_001367561.1; = p.V1018= on NM_033407.3) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV52014034; called by muse, mutect2, varscan2
- DOCK8 | c.3837C>T p.S1279= | Silent (SNP) | VAF 199/341 reads (58%) | catalogued as COSV66622102; called by muse, mutect2, varscan2
- DSG4 | c.1800C>T p.A600= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs745538080, COSV57394564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP22 | c.303A>G p.A101= | Silent (SNP) | VAF 40/271 reads (15%) | catalogued as rs773584633, COSV100739738; called by muse, mutect2, varscan2
- EFNB3 | c.978G>A p.Q326= | Silent (SNP) | VAF 35/39 reads (90%) | catalogued as COSV56833989; called by muse, varscan2
- EI24 | c.573G>A p.V191= | Silent (SNP) | VAF 143/326 reads (44%) | catalogued as COSV54019327, COSV54020254; called by muse, mutect2, varscan2
- EML1 | c.2370C>T p.V790= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs113496186, COSV51741848; called by mutect2, varscan2
- EPB41 | c.600C>T p.S200= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV100548442; called by muse, mutect2, varscan2
- ESR2 | c.1086G>A p.L362= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as rs1270843484, COSV50835475; called by muse, mutect2, varscan2
- EXT1 | c.1755C>T p.F585= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV65482429; called by muse, mutect2, varscan2
- FAM161B | c.672C>T p.S224= (on ENST00000651776; = p.S161= on NM_152445.3) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs768319693, COSV54102784; called by mutect2, varscan2
- FAT3 | c.9420C>T p.V3140= | Silent (SNP) | VAF 144/346 reads (42%) | catalogued as COSV53144917; called by muse, mutect2, varscan2
- FBXO41 | c.948G>A p.A316= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs781382924, COSV54587269; called by mutect2, varscan2
- FLT4 | c.888C>T p.T296= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV56099040, COSV56115924; called by muse, mutect2, varscan2
- FOXI1 | c.12C>T p.F4= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs757881412, COSV60387990; called by muse, mutect2, varscan2
- GAGE10 | c.292C>T p.L98= | Silent (SNP) | VAF 84/90 reads (93%) | catalogued as COSV68164091; called by muse, mutect2, varscan2
- GNB4 | c.381G>A p.K127= | Silent (SNP) | VAF 115/255 reads (45%) | catalogued as COSV51710634; called by muse, mutect2, varscan2
- GP2 | c.174C>T p.V58= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV56895370; called by muse, mutect2, varscan2
- GPR142 | c.555C>T p.A185= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV59519930; called by muse, mutect2, varscan2
- GRIA1 | c.1593C>T p.F531= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV53613936; called by muse, mutect2, varscan2
- HAPLN3 | c.15C>T p.L5= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100613718; called by muse, mutect2, varscan2
- HCN1 | c.558C>T p.F186= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1060500097, COSV57495408; called by muse, mutect2, varscan2
- HIF3A | c.1227C>T p.F409= (on ENST00000377670 / NM_152795.4; = p.F340= on NM_022462.4) | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52198168; called by muse, mutect2, varscan2
- HINT2 | c.345C>T p.L115= | Silent (SNP) | VAF 100/168 reads (60%) | catalogued as rs759860704, COSV99427867, COSV99428006; called by muse, mutect2, varscan2
- HLA-DQA2 | c.537C>T p.F179= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as COSV66566072; called by muse, mutect2, varscan2
- HOMER2 | c.189G>A p.P63= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs746991345, COSV58487283; called by muse, mutect2, varscan2
- HPS1 | c.630C>T p.F210= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV57269111; called by muse, mutect2, varscan2
- HYDIN | c.13224G>A p.G4408= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV101125067; called by muse, mutect2, varscan2
- IGHA1 | c.591C>T p.N197= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs780199602; called by muse, mutect2, varscan2
- IGHD | c.624G>A p.G208= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs267603901, COSV101162863; called by muse, varscan2
- IGHV3-15 | c.27C>T p.F9= | Silent (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.27C>T p.F9= | Silent (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- IGHV3-73 | c.15G>A p.L5= | Silent (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- IL22RA1 | c.1563C>T p.S521= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV54629517; called by muse, mutect2
- INO80 | c.1341T>C p.F447= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs759826144, COSV62740348; called by muse, mutect2, varscan2
- INTS14 | c.729C>T p.I243= (on ENST00000313182 / NM_001366360.2; = p.I164= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1302450441, COSV57527580; called by muse, mutect2, varscan2
- IPO13 | c.1533C>T p.F511= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV64894758; called by muse, mutect2, varscan2
- IQUB | c.1656C>T p.V552= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV61240908; called by mutect2, varscan2
- ITPR2 | c.2040G>A p.E680= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs1176661834, COSV67272806; called by muse, varscan2
- KALRN | c.1776C>T p.T592= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV53773247; called by muse, mutect2, varscan2
- KCND3 | c.1062C>T p.I354= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs150934088, COSV56185108; called by muse, mutect2, varscan2
- KDM3B | c.3726C>T p.S1242= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as COSV58693066; called by muse, mutect2, varscan2
- LAMB3 | c.2523C>T p.G841= | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as COSV61918196; called by muse, mutect2, varscan2
- LENG8 | c.726C>T p.P242= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58729105; called by muse, mutect2, varscan2
- LRP1B | c.1863G>A p.R621= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV67186904; called by muse, mutect2, varscan2
- MAP2 | c.2115G>A p.P705= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs376603789; called by muse, mutect2, varscan2
- MAP4K1 | c.954C>T p.I318= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs757660172, COSV67711678; called by mutect2, varscan2
- MEFV | c.2034G>A p.G678= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV54824851; called by muse, mutect2, varscan2
- MGAT1 | c.555C>T p.I185= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs147959494; called by muse, mutect2, varscan2
- MROH1 | c.2919C>T p.S973= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1018619838; called by muse, mutect2, varscan2
- MUC4 | c.2247G>A p.G749= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV62168192; called by muse, mutect2, varscan2
- MUC4 | c.1632G>A p.E544= | Silent (SNP) | VAF 75/149 reads (50%) | catalogued as rs775523629, COSV62168201; called by muse, mutect2, varscan2
- MYH9 | c.2358C>T p.F786= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV53390007; called by muse, mutect2, varscan2
- MYO18B | c.7077G>A p.P2359= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs370775470; called by muse, varscan2
- MYT1L | c.2343G>A p.R781= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV67726376; called by muse, mutect2, varscan2
- NARS2 | c.1404C>T p.F468= | Silent (SNP) | VAF 113/253 reads (45%) | catalogued as COSV55253803; called by muse, mutect2, varscan2
- NCKAP5 | c.3144C>T p.T1048= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV58460679; called by muse, mutect2, varscan2
- NCKAP5L | c.3438G>A p.K1146= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV60131421; called by muse, mutect2, varscan2
- NCOA3 | c.1968C>T p.P656= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs1185020695, COSV59070972; called by muse, varscan2
- NLRP2 | c.411G>A p.T137= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs756188251, COSV54753405; called by muse, mutect2, varscan2
- NOL4 | c.144G>A p.T48= | Silent (SNP) | VAF 66/106 reads (62%) | catalogued as rs759397338, COSV52354039; called by muse, mutect2, varscan2
- NPY2R | c.417C>T p.I139= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV61528936; called by muse, mutect2, varscan2
- NTS | c.450G>A p.R150= | Silent (SNP) | VAF 83/179 reads (46%) | catalogued as rs376727328; called by muse, mutect2, varscan2
- OBP2B | c.351G>A p.Q117= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as rs782754774, COSV64402690; called by muse, mutect2, varscan2
- OR10Z1 | c.186C>T p.F62= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV63523809; called by muse, mutect2, varscan2
- OR14A16 | c.414C>T p.T138= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs771359251, COSV100713706, COSV62927121; called by muse, mutect2, varscan2
- OR2A5 | c.900C>T p.A300= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV68738939; called by muse, mutect2
- OR2B2 | c.306C>T p.F102= | Silent (SNP) | VAF 62/92 reads (67%) | catalogued as COSV57580132; called by muse, mutect2, varscan2
- OR2T34 | c.726C>T p.A242= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as rs751818126, COSV60900437, COSV60901142; called by muse, mutect2, varscan2
- OR2T8 | c.96C>T p.I32= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs369748850; called by muse, mutect2, varscan2
- OR4C12 | c.654C>T p.I218= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV58860599; called by mutect2, varscan2
- OR4K2 | c.336C>T p.I112= | Silent (SNP) | VAF 49/256 reads (19%) | catalogued as rs754020790, COSV53848253; called by muse, mutect2, varscan2
- OR4P4 | c.607T>C p.L203= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58922901; called by muse, varscan2
- OR4S2 | c.468C>T p.I156= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100412636, COSV56747003; called by muse, mutect2, varscan2
- OR51E2 | c.339C>T p.I113= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs201467711, COSV67807554; called by muse, mutect2, varscan2
- OR52E2 | c.948G>A p.K316= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV58613079; called by muse, mutect2, varscan2
- OR5H14 | c.84C>T p.F28= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV71194262, COSV71194264; called by muse, mutect2, varscan2
- OR6A2 | c.534C>T p.I178= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV60265445; called by muse, mutect2, varscan2
- OR6C74 | c.93C>T p.F31= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV59605695, COSV59606861; called by muse, mutect2, varscan2
- OTOP1 | c.834G>A p.Q278= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV56392178; called by muse, mutect2, varscan2
- PACSIN1 | c.1206C>T p.D402= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs1376288018, COSV55059712; called by muse, mutect2, varscan2
- PAPPA2 | c.2259C>T p.S753= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV62782176; called by muse, mutect2, varscan2
- PAPPA2 | c.4248C>T p.L1416= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs1486494592, COSV62804616; called by muse, mutect2, varscan2
- PARP12 | c.1974C>T p.P658= | Silent (SNP) | VAF 99/128 reads (77%) | catalogued as COSV54935853; called by muse, mutect2, varscan2
- PCDH12 | c.2259G>A p.R753= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV51522982; called by muse, mutect2, varscan2
- PCDHA7 | c.1113G>A p.L371= | Silent (SNP) | VAF 76/163 reads (47%) | catalogued as COSV65345901; called by muse, mutect2, varscan2
- PCDHA7 | c.1371G>A p.Q457= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV65345909; called by muse, mutect2, varscan2
- PCDHGB4 | c.2154C>T p.S718= | Silent (SNP) | VAF 77/217 reads (35%) | catalogued as COSV53983005; called by muse, mutect2, varscan2
- PDE4A | c.912G>A p.T304= (on ENST00000380702 / NM_001111307.2; = p.T65= on NM_006202.3) | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs375043820, COSV53359221; called by mutect2, varscan2
- PDE6B | c.2046C>T p.I682= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs774172884, COSV55328623; called by muse, mutect2, varscan2
- PHRF1 | c.3939C>T p.S1313= (on ENST00000264555 / NM_001286581.2; = p.S1312= on NM_020901.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99200176; called by muse, mutect2, varscan2
- PHRF1 | c.3940C>T p.L1314= (on ENST00000264555 / NM_001286581.2; = p.L1313= on NM_020901.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs771185740, COSV99200201; called by muse, mutect2, varscan2
- PID1 | c.582G>A p.Q194= (on ENST00000354069 / NM_001330156.1; = p.Q192= on NM_017933.5) | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV62479084; called by muse, mutect2, varscan2
- PLA2G4E | c.792C>T p.Y264= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV68151184; called by muse, mutect2, varscan2
- PRAMEF18 | c.585C>T p.F195= | Silent (SNP) | VAF 95/540 reads (18%) | called by muse, mutect2, varscan2
- PRKCB | c.1032C>T p.F344= | Silent (SNP) | VAF 104/220 reads (47%) | catalogued as COSV57790375; called by muse, mutect2, varscan2
- PSD | c.2238C>T p.F746= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV50050698; called by muse, mutect2, varscan2
- QSER1 | c.1578C>T p.S526= (on ENST00000399302; = p.S655= on NM_001076786.3) | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV67899608, COSV67901207; called by muse, mutect2, varscan2
- RGMA | c.150C>T p.I50= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61235661; called by muse, mutect2, varscan2
- RUNX2 | c.792G>A p.Q264= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as rs12173874, COSV61843667; called by muse, mutect2, varscan2
- SAMD11 | c.933C>T p.P311= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58989263; called by muse, mutect2, varscan2
- SCN9A | c.2565G>A p.L855= (on ENST00000303354; = p.L844= on NM_002977.3) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1268900258, COSV57617270; called by mutect2, varscan2
- SEPTIN4 | c.1554C>T p.F518= | Silent (SNP) | VAF 69/216 reads (32%) | catalogued as COSV58727230, COSV58728579; called by muse, mutect2, varscan2
- SERPINE2 | c.636G>A p.G212= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1325336294, COSV51458918; called by muse, varscan2
- SFTPA1 | c.708G>A p.R236= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs769709869, COSV64867420; called by muse, mutect2, varscan2
- SHANK2 | c.3837G>A p.E1279= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV53609309; called by muse, mutect2, varscan2
- SHKBP1 | c.153A>G p.G51= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52541818; called by muse, mutect2
- SLC14A2 | c.1239G>A p.T413= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs149835341; called by muse, mutect2, varscan2
- SLC2A10 | c.147C>T p.F49= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV63714229; called by muse, mutect2, varscan2
- SLC38A3 | c.891C>T p.F297= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1307546993, COSV68843969; called by muse, mutect2, varscan2
- SLC4A3 | c.2577G>A p.E859= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56095835; called by muse, mutect2, varscan2
- SLCO4C1 | c.2174G>A p.*725= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV60518161; called by muse, mutect2, varscan2
- SLIT3 | c.621C>T p.I207= | Silent (SNP) | VAF 77/172 reads (45%) | catalogued as COSV60622473; called by muse, mutect2, varscan2
- SMAD6 | c.1161C>T p.I387= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs777669717, COSV56596181; called by mutect2, varscan2
- STAB2 | c.3273C>T p.F1091= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs751626024, COSV66333499; called by muse, mutect2, varscan2
- SYNGR1 | c.351C>T p.F117= | Silent (SNP) | VAF 77/145 reads (53%) | catalogued as COSV53368131; called by muse, mutect2, varscan2
- TBXA2R | c.36C>T p.F12= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV64344189; called by muse, mutect2, varscan2
- TM4SF18 | c.297C>T p.L99= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs769129238, COSV56059562; called by mutect2, varscan2
- TMC6 | c.1035C>T p.S345= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV59810144; called by muse, mutect2, varscan2
- TMEM108 | c.300C>A p.I100= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV58871690, COSV58875188, COSV58876866; called by muse, mutect2, varscan2
- TMEM184A | c.1237C>T p.L413= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs914069077, COSV52474745; called by muse, varscan2
- TNS4 | c.645G>T p.L215= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV54186767; called by muse, mutect2, varscan2
- TRBV6-1 | c.150C>T p.S50= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2
- TRIML1 | c.963G>A p.P321= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs757005539, COSV100205985; called by muse, mutect2, varscan2
- TRPC5 | c.417C>T p.F139= | Silent (SNP) | VAF 45/53 reads (85%) | catalogued as COSV53297394; called by muse, mutect2, varscan2
- TRPC6 | c.294G>A p.E98= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100723644, COSV60258048; called by muse, mutect2, varscan2
- TRUB2 | c.826C>T p.L276= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs181741722, COSV65759999; called by muse, mutect2, varscan2
- TSNARE1 | c.964C>T p.L322= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV56179816; called by muse, mutect2, varscan2
- TTI2 | c.426C>T p.G142= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV62453116; called by muse, mutect2, varscan2
- TTN | c.24009C>T p.S8003= (on ENST00000591111; = p.S7076= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1057522331, COSV60199250; ClinVar: likely benign; called by muse, mutect2, varscan2
- TYK2 | c.3309C>T p.S1103= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as rs894692852, COSV53385889; called by muse, varscan2
- UBTD2 | c.621C>T p.F207= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs1291209601, COSV67142625; called by muse, mutect2, varscan2
- UGT2B11 | c.567C>T p.F189= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV71423153, COSV71423251; called by muse, mutect2, varscan2
- USP43 | c.3084C>G p.G1028= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV53304986; called by muse, varscan2
- VWA3B | c.3741C>T p.A1247= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV71370152; called by muse, mutect2, varscan2
- VWA5A | c.294C>T p.F98= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV63707931; called by muse, mutect2, varscan2
- XKR4 | c.1689C>T p.F563= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as rs753165731, COSV59316870; called by muse, mutect2, varscan2
- XKR6 | c.1038G>A p.R346= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as COSV58655634; called by muse, varscan2
- YKT6 | c.444G>A p.E148= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV56272815; called by muse, mutect2, varscan2
- ZAN | c.2577C>T p.I859= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as rs1468460384, COSV61812153; called by muse, mutect2, varscan2
- ZBED6CL | c.67C>T p.L23= | Silent (SNP) | VAF 69/101 reads (68%) | catalogued as COSV59605051; called by muse, mutect2, varscan2
- ZBTB7C | c.1677C>T p.F559= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs767758757, COSV59689856; called by muse, mutect2, varscan2
- ZDHHC19 | c.27G>A p.P9= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs775134058, COSV56349401; called by muse, mutect2, varscan2
- ZNF518B | c.1605A>G p.A535= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV58723633; called by muse, mutect2, varscan2
- ZNF560 | c.2148C>T p.D716= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV56869759, COSV56871552; called by muse, mutect2, varscan2
- ZSWIM2 | c.999G>A p.K333= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV54577294; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11561G>A | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99173272; called by muse, mutect2, varscan2
- GLRXP3 | n.280G>A | RNA (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- MIR1324 | n.26C>T | RNA (SNP) | VAF 9/68 reads (13%) | catalogued as rs756396218; called by mutect2, varscan2
- MORF4 | n.399C>T | RNA (SNP) | VAF 42/85 reads (49%) | catalogued as rs375467455; called by mutect2, varscan2
- RPL26P30 | n.996G>A | RNA (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- SERPINA13P | n.501C>T | RNA (SNP) | VAF 6/10 reads (60%) | catalogued as rs774453759; called by muse, mutect2, varscan2
- SNORD114-14 | n.65C>T | RNA (SNP) | VAF 18/38 reads (47%) | catalogued as rs758111212; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2271G>A | Intron (SNP) | VAF 46/101 reads (46%) | catalogued as rs1358401250, COSV100314192; called by muse, mutect2, varscan2
- UBTFL2 | n.506G>A | RNA (SNP) | VAF 10/28 reads (36%) | catalogued as rs746576752; called by mutect2, varscan2
